TARGET case TARGET-10-PAPCXR — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a275435d-76f8-5e37-8b96-a99837e34b25

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 15 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.6 years (5,710 days); Year of diagnosis: 2005; Days to last follow up: 3,848 days (10.5 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (1 entry)
- Days to follow up: 3,848 days (10.5 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,848; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 68.9 ×10³/µL.
- Day 8: Bone Marrow blast count 32%.
- Day 15: Bone Marrow blast count 1%.
- Day 29: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 0%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (5 samples)
- Sample TARGET-10-PAPCXR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAPCXR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Samples TARGET-10-PAPCXR-60.1C, TARGET-10-PAPCXR-60.2C, TARGET-10-PAPCXR-60.3C (3 with the same recorded description): Sample type: Primary Xenograft Tissue; Tissue type: Tumor; Tumor descriptor: Xenograft.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 3848
- WBC at Diagnosis: 68.9
- CNS Status at Diagnosis: CNS 3
- Testicular Involvement: No
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 32
- BMA Blasts Day 15: 1
- BMA Blasts Day 29: 2
- Karyotype: 46,XY,t(5;5)(q13;q31)[12]/46,XY[8]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- CNS Status at Diagnosis: CNS 3c
- Cell of Origin: B Cell ALL
